Somatic mutation profile of tumor specimen 0DJ6KO from CCDI case PBBWGV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.5 years (6,017 days).
Specimen 0DJ6KO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f43f7c5-6bf6-496b-a9ee-2ff85b396eef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0cd6b5e-398e-4478-85a5-73cc6c1347cd

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 5'UTR 4, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/435 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 137/411 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 1049/1431 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs397507544, CM044932, COSV61005111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHRR | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 257/1208 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1161216045; called by muse, mutect2, varscan2
- CYFIP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 65/469 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1414587779; called by muse, mutect2, varscan2
- GPR156 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 81/568 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs372902834; called by muse, mutect2, varscan2
- GTPBP1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 348/752 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs775495102; called by muse, mutect2, varscan2
- KRT9 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 304/830 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs201047019, COSV99879245; called by muse, mutect2, varscan2
- MAGEL2 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 135/978 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.967); catalogued as rs1431804565; called by muse, mutect2, varscan2
- RYR2 | c.6773G>A p.R2258H | Missense Mutation (SNP) | VAF 68/810 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs779289104, COSV63697988; called by muse, mutect2
- SLC12A6 | c.2024G>A p.R675Q (on ENST00000354181 / NM_001365088.1; = p.R624Q on NM_005135.2) | Missense Mutation (SNP) | VAF 257/730 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99271565; called by muse, mutect2, varscan2
- ANO5 | c.1096A>T p.N366Y | Missense Mutation (SNP) | VAF 85/394 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ATRX | c.5345del p.N1782Ifs*14 | Frame Shift Del (DEL) | VAF 121/254 reads (48%) | called by mutect2, pindel, varscan2
- CHD1 | c.4134G>T p.R1378S | Missense Mutation (SNP) | VAF 79/540 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TP53I13 | c.911C>A p.T304N | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- WSB2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 231/615 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTROB | c.552G>A p.Q184= | Silent (SNP) | VAF 89/1054 reads (8%) | called by muse, mutect2
- CORO1B | c.1467G>A p.A489= | Silent (SNP) | VAF 66/294 reads (22%) | catalogued as rs202196580, COSV57053917; called by muse, mutect2, varscan2
- DPEP1 | c.63C>T p.D21= | Silent (SNP) | VAF 86/434 reads (20%) | catalogued as rs371346042; called by muse, mutect2, varscan2
- NGEF | c.2112G>A p.L704= | Silent (SNP) | VAF 60/681 reads (9%) | called by muse, mutect2
- RFC5 | c.972C>T p.S324= | Silent (SNP) | VAF 578/1345 reads (43%) | catalogued as COSV57478288; called by muse, varscan2
- BBC3 | c.-1G>A | 5'UTR (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- BBC3 | c.-84G>C | 5'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- CRLF1 | c.*87G>C | 3'UTR (SNP) | VAF 31/315 reads (10%) | called by muse, varscan2
- MRM2 | c.-23C>G | 5'UTR (SNP) | VAF 213/624 reads (34%) | catalogued as rs747114574; called by muse, mutect2, varscan2
- QRSL1 | c.-25T>C | 5'UTR (SNP) | VAF 115/279 reads (41%) | called by muse, mutect2, varscan2
- WSB2 | c.1052+55G>A | Intron (SNP) | VAF 192/502 reads (38%) | called by muse, mutect2, varscan2
